Gene-level copy-number profile of tumor specimen TCGA-ZF-AA4R-01A from TCGA case TCGA-ZF-AA4R, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 67.2 years (24,537 days).
Specimen TCGA-ZF-AA4R-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.2498c37c-90af-4107-a5cb-6d866a0a87d1.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-ZF-AA4R-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/25ba9685-2ca6-47b8-9afa-812cc2391282

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 10,345; copy number 2: 36,455; copy number 3: 8,130; copy number 4: 3,605; copy number 5: 493; copy number 6: 257; copy number 7: 83; copy number 8: 111; copy number 9: 3; copy number 10: 68; copy number 11: 44; copy number 12: 21; copy number 13: 202.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-ZF-AA4R-01A-11D-A38F-01): tumor purity 0.66, ploidy 2.15, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,282 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:147,019,656–147,124,285, 6 genes, copy number 10 (within-gene range 4–10): AC244394.2, AC244394.1, RNU1-151P, SSBL4P, RNVU1-8, NBPF13P.
- chr1:149,782,671–173,064,015, 864 genes, copy number 5–13 (within-gene range 2–13) (broad region; genes not listed).
- chr1:197,268,204–197,935,478, 11 genes, copy number 5 (within-gene range 3–5): CRB1, MRPS21P3, AL136322.1, DENND1B, Y_RNA, EEF1A1P32, AL365258.2, FAM204BP, AL365258.1, C1orf53, LHX9.
- chr5:54,643,557–56,606,232, 57 genes, copy number 7 (within-gene range 4–7): AC016583.1, AC016583.2, CSPG4BP, AC112198.1, AC112198.3, AC112198.2, ESM1, AC034238.1, GZMK, Y_RNA, AC034238.3, AC034238.2, GZMAP1, GZMA, CDC20B, GPX8, MIR449A, MIR449B, MIR449C, MCIDAS, CCNO, AC026704.1, DHX29, MTREX, AC020728.1, PLPP1, AC010480.1, MIR5687, RNF138P1, AK4P2, SLC38A9, DDX4, AC016632.1, RNA5SP183, HNRNPH1P3, IL31RA, IL6ST, AC008914.1, AC016596.2, AC008892.1, FLJ31104, AC016596.1, ANKRD55, RNU6-299P, RPL17P22, RNA5SP184, C1GALT1P2, RNA5SP185, PSMC1P4, RNU6ATAC2P, AC034245.1, HMGN1P17, LINC01948, AC008391.1, RPL26P19, C5orf67, AC022431.1.
- chr7:16,888,621–17,940,501, 12 genes, copy number 7–9 (within-gene range 4–9): AC098592.2, AHR, AC098592.1, AC073332.1, BRWD1P3, Metazoa_SRP, AC019117.3, SNORA63, AC019117.2, AC019117.1, AC006482.1, SNX13.
- chr8:33,604,856–34,039,104, 1 gene, copy number 7 (within-gene range 3–7): AF279873.3.
- chr8:33,715,784–40,402,010, 120 genes, copy number 7–13 (broad region; genes not listed).
- chr10:2,724,819–13,668,445, 202 genes, copy number 8–13 (broad region; genes not listed).
- chr10:13,675,646–13,871,175, 5 genes, copy number 13: AL157392.4, AL157392.1, RNA5SP301, AL157392.2, NUTF2P5.
- chr16:70,802,084–71,230,722, 4 genes, copy number 7 (within-gene range 2–7): HYDIN, RNU6ATAC25P, AC138625.2, AC138625.1.

Autosomal genes at a single copy (total copy number 1): 7,924. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
